Somatic mutation profile of tumor specimen TCGA-DD-A4NN-01A (aliquot TCGA-DD-A4NN-01A-11D-A28X-10) from TCGA case TCGA-DD-A4NN, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 56.3 years (20,548 days).
Specimen TCGA-DD-A4NN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1fd579ff-c421-4825-9f91-ff852e5c09bc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A4NN-10A (Blood Derived Normal), aliquot TCGA-DD-A4NN-10A-01D-A28X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ae2676a6-fcdb-42af-8184-30bf3526f862

The open-access MAF lists 58 somatic variants for this specimen: 42 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 14, Frame Shift Del 4, Frame Shift Ins 3, 3'UTR 1, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABR | c.2526dup p.I843Hfs*46 (on ENST00000302538 / NM_021962.5; = p.I806Hfs*46 on NM_001092.5) | Frame Shift Ins (INS) | VAF 38/118 reads (32%) | catalogued as rs750897785; called by mutect2, varscan2
- AGAP1 | c.2533A>G p.N845D (on ENST00000304032 / NM_001037131.3; = p.N792D on NM_014914.5) | Missense Mutation (SNP) | VAF 159/350 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as COSV58328596; called by muse, mutect2, varscan2
- BBS2 | c.251A>T p.N84I | Missense Mutation (SNP) | VAF 101/131 reads (77%) | SIFT tolerated (0.17); PolyPhen benign (0.036); catalogued as COSV55326898; called by muse, mutect2, varscan2
- BRD4 | c.3994G>T p.E1332* | Nonsense Mutation (SNP) | VAF 62/125 reads (50%) | catalogued as COSV54587419; called by muse, mutect2, varscan2
- CACNA1E | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 65/392 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.07); catalogued as rs369308237; called by muse, mutect2, varscan2
- CDH19 | c.22C>G p.R8G | Missense Mutation (SNP) | VAF 71/132 reads (54%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV50961258; called by muse, mutect2, varscan2
- CHERP | c.1734C>G p.F578L | Missense Mutation (SNP) | VAF 61/172 reads (35%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.219); catalogued as COSV52225223; called by muse, mutect2, varscan2
- CIZ1 | c.1171G>A p.V391M | Missense Mutation (SNP) | VAF 77/166 reads (46%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.36); catalogued as rs780756425, COSV52971984; called by muse, mutect2, varscan2
- CXXC5 | c.745C>G p.L249V | Missense Mutation (SNP) | VAF 8/113 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.458); catalogued as COSV56794071; called by muse, mutect2
- DMD | c.7652C>T p.T2551M | Missense Mutation (SNP) | VAF 62/184 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs778691311, COSV58900244; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH7 | c.607A>G p.I203V | Missense Mutation (SNP) | VAF 59/116 reads (51%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as COSV56768827; called by muse, mutect2, varscan2
- DOCK8 | c.4606T>C p.F1536L | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as COSV66620736; called by muse, mutect2, varscan2
- GAS2 | c.663C>G p.F221L | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.177); catalogued as COSV53408383; called by muse, mutect2, varscan2
- GPAT3 | c.128T>A p.V43E | Missense Mutation (SNP) | VAF 27/34 reads (79%) | SIFT deleterious (0.01); PolyPhen benign (0.169); catalogued as COSV52357513; called by muse, mutect2, varscan2
- GPR52 | c.434A>T p.K145M | Missense Mutation (SNP) | VAF 148/378 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV52300948; called by muse, mutect2, varscan2
- HMCN1 | c.11800G>A p.G3934S | Missense Mutation (SNP) | VAF 92/282 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs771776707, COSV54901157, COSV99627594; called by muse, mutect2, varscan2
- ITGAL | c.2807A>G p.Y936C | Missense Mutation (SNP) | VAF 62/115 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63322626; called by muse, varscan2
- ITGAM | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 58/184 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1567249191, COSV54938026; called by muse, mutect2, varscan2
- MAGEE1 | c.1577G>A p.R526H | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV63910591; called by muse, mutect2, varscan2
- MARCHF6 | c.703G>C p.D235H | Missense Mutation (SNP) | VAF 53/232 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.058); catalogued as COSV56882406; called by muse, mutect2, varscan2
- MLXIPL | c.857T>G p.L286R | Missense Mutation (SNP) | VAF 72/156 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV57668617; called by muse, mutect2, varscan2
- NAV2 | c.5018C>T p.S1673F (on ENST00000396087 / NM_001244963.2; = p.S1617F on NM_145117.5) | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60660292; called by muse, mutect2, varscan2
- PKD1L1 | c.5858A>G p.H1953R | Missense Mutation (SNP) | VAF 77/343 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.172); catalogued as COSV56967613; called by muse, mutect2, varscan2
- POM121L12 | c.584C>G p.P195R | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV101374925, COSV68693180; called by muse, varscan2
- RECQL4 | c.748G>C p.G250R | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.132); catalogued as COSV52880056; called by muse, mutect2, varscan2
- ROBO1 | c.127C>T p.P43S | Missense Mutation (SNP) | VAF 139/310 reads (45%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.068); catalogued as COSV71969418; called by muse, mutect2, varscan2
- SEMA6C | c.683A>G p.Q228R | Missense Mutation (SNP) | VAF 30/552 reads (5%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV59004003; called by muse, mutect2
- SPTA1 | c.3226C>T p.R1076C | Missense Mutation (SNP) | VAF 102/283 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.917); catalogued as rs372281474, COSV63754644; called by muse, mutect2, varscan2
- SPTA1 | c.2921A>G p.E974G | Missense Mutation (SNP) | VAF 32/213 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV63754648; called by muse, mutect2, varscan2
- SV2C | c.293G>T p.S98I | Missense Mutation (SNP) | VAF 77/183 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.036); catalogued as COSV59221610; called by muse, mutect2, varscan2
- THSD7A | c.1082G>A p.C361Y | Missense Mutation (SNP) | VAF 56/128 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs558393471, COSV70266214; called by muse, mutect2, varscan2
- TP53BP2 | c.3388C>G p.Q1130E (on ENST00000343537 / NM_001031685.3; = p.Q1001E on NM_005426.2) | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54336805; called by muse, mutect2
- TSEN34 | c.557A>G p.Q186R | Missense Mutation (SNP) | VAF 120/243 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs755901797, COSV55476176; called by muse, mutect2, varscan2
- UNC13C | c.6114del p.S2039Pfs*27 | Frame Shift Del (DEL) | VAF 34/111 reads (31%) | catalogued as COSV52848897; called by mutect2, pindel, varscan2
- WDFY3 | c.2545C>T p.P849S | Missense Mutation (SNP) | VAF 157/214 reads (73%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.53); catalogued as COSV55703525; called by muse, mutect2, varscan2
- ZNF431 | c.1541G>A p.C514Y | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60673580; called by muse, mutect2, varscan2
- ZNF585A | c.2168G>T p.C723F (on ENST00000292841 / NM_001288800.2; = p.C668F on NM_152655.3) | Missense Mutation (SNP) | VAF 121/313 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53064498; called by muse, mutect2, varscan2
- CCDC151 | c.1082dup p.V362Gfs*8 | Frame Shift Ins (INS) | VAF 8/53 reads (15%) | called by mutect2, pindel, varscan2
- ERRFI1 | c.316_326delinsT p.H106Ffs*12 | Frame Shift Del (DEL) | VAF 37/47 reads (79%) | called by pindel, varscan2*
- FHOD3 | c.3925_3926insGT p.E1309Gfs*6 (on ENST00000359247 / NM_001281739.3; = p.E1326Gfs*6 on NM_025135.5) | Frame Shift Ins (INS) | VAF 75/159 reads (47%) | called by mutect2, pindel, varscan2
- INSRR | c.33_40del p.L13Dfs*104 | Frame Shift Del (DEL) | VAF 46/358 reads (13%) | called by mutect2, pindel
- OR10C1 | c.471del p.L158Wfs*89 (on ENST00000622521; = p.L156Wfs*89 on NM_013941.3) | Frame Shift Del (DEL) | VAF 47/172 reads (27%) | called by mutect2, pindel, varscan2
- ADAMTS1 | c.2256A>G p.E752= | Silent (SNP) | VAF 35/79 reads (44%) | catalogued as COSV53170971; called by muse, mutect2, varscan2
- ADNP | c.2685T>G p.P895= | Silent (SNP) | VAF 83/154 reads (54%) | catalogued as COSV62425757; called by muse, mutect2, varscan2
- AGAP2 | c.1836C>T p.L612= (on ENST00000547588 / NM_001122772.2; = p.L276= on NM_014770.4) | Silent (SNP) | VAF 48/103 reads (47%) | catalogued as rs750480607, COSV57728860; called by muse, mutect2, varscan2
- APC2 | c.729G>A p.A243= | Silent (SNP) | VAF 64/190 reads (34%) | catalogued as rs138830892, COSV52019327; called by muse, mutect2, varscan2
- BCL2L1 | c.279A>T p.A93= | Silent (SNP) | VAF 77/258 reads (30%) | catalogued as COSV56967949; called by muse, mutect2, varscan2
- CERS5 | c.810C>T p.D270= | Silent (SNP) | VAF 41/108 reads (38%) | catalogued as COSV58189398; called by muse, mutect2, varscan2
- EDNRB | c.1452A>G p.K484= (on ENST00000377211 / NM_001201397.1; = p.K394= on NM_000115.5) | Silent (SNP) | VAF 15/19 reads (79%) | catalogued as COSV57523626; called by muse, mutect2, varscan2
- FGF20 | c.516C>T p.D172= | Silent (SNP) | VAF 46/138 reads (33%) | catalogued as rs376980441; called by muse, mutect2, varscan2
- IFNAR1 | c.1041T>C p.H347= | Silent (SNP) | VAF 42/91 reads (46%) | catalogued as COSV54252433; called by muse, mutect2, varscan2
- MYOM2 | c.2832T>C p.C944= | Silent (SNP) | VAF 106/174 reads (61%) | catalogued as COSV50721237; called by muse, mutect2
- NECTIN4 | c.1149C>T p.T383= | Silent (SNP) | VAF 117/593 reads (20%) | catalogued as COSV63512985; called by muse, mutect2, varscan2
- PGLYRP3 | c.357C>A p.A119= | Silent (SNP) | VAF 104/553 reads (19%) | catalogued as COSV51950707; called by muse, mutect2, varscan2
- SPIDR | c.756A>T p.S252= | Silent (SNP) | VAF 38/87 reads (44%) | catalogued as COSV52379618; called by muse, mutect2, varscan2
- ZNF461 | c.1122A>T p.I374= | Silent (SNP) | VAF 38/88 reads (43%) | catalogued as COSV64453985; called by muse, mutect2, varscan2
- CLU | c.-38C>T | 5'UTR (SNP) | VAF 199/240 reads (83%) | catalogued as rs1055426723, COSV100324472, COSV57066444; called by muse, mutect2, varscan2
- DDX41 | c.*283C>A | 3'UTR (SNP) | VAF 95/196 reads (48%) | catalogued as COSV57252819; called by muse, mutect2, varscan2
